Somatic mutation profile of tumor specimen TCGA-EA-A3Y4-01A (aliquot TCGA-EA-A3Y4-01A-51D-A243-09) from TCGA case TCGA-EA-A3Y4, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 40.3 years (14,706 days).
Specimen TCGA-EA-A3Y4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1726e4e8-dd52-4a72-8da4-5b351327a0e2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EA-A3Y4-10A (Blood Derived Normal), aliquot TCGA-EA-A3Y4-10A-01D-A243-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f3adebad-e5ad-4d67-8fbe-56bb557ba831

The open-access MAF lists 138 somatic variants for this specimen: 97 protein-altering or splice-affecting, 37 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 85, Silent 37, Nonsense Mutation 7, Splice Site 2, 5'UTR 1, Frame Shift Del 1, 5'Flank 1, RNA 1, Intron 1, Nonstop Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADD2 | c.717G>A p.M239I | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.667); catalogued as rs782070720, COSV52473889; called by muse, mutect2, varscan2
- CACNA1H | c.3940G>C p.E1314Q | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV61993019; called by muse, mutect2, varscan2
- CAPRIN1 | c.791C>G p.S264* | Nonsense Mutation (SNP) | VAF 22/70 reads (31%) | catalogued as COSV58222515; called by muse, mutect2, varscan2
- COL22A1 | c.4160G>C p.G1387A | Missense Mutation (SNP) | VAF 4/89 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100278254; called by muse, mutect2
- CSMD2 | c.4771G>C p.E1591Q | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT tolerated (0.7); PolyPhen benign (0.014); catalogued as COSV53920724; called by muse, mutect2, varscan2
- DHRSX | c.506C>T p.S169F | Missense Mutation (SNP) | VAF 36/148 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs773647562; called by muse, mutect2, varscan2
- EDEM3 | c.2369C>G p.S790C | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.789); catalogued as COSV58921274, COSV58928843; called by muse, mutect2, varscan2
- EPHB1 | c.391G>C p.E131Q | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.782); catalogued as COSV67675165; called by muse, mutect2, varscan2
- FAT3 | c.1802C>T p.S601L | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1395732545; called by muse, mutect2
- FRS2 | c.1085G>A p.R362H | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs775308985, COSV54725947; called by muse, mutect2, varscan2
- HCK | c.1240C>T p.R414W | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs774033506, COSV52945363; called by muse, mutect2, varscan2
- HLA-A | c.360G>C p.Q120H | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as rs199474481, COSV65138007; called by muse, varscan2
- ITM2B | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.045); catalogued as COSV66035214, COSV66035331; called by muse, mutect2
- KHDC3L | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.98); catalogued as COSV64869115; called by muse, mutect2, varscan2
- KIAA0232 | c.677A>G p.N226S | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0.031); catalogued as rs1406868471; called by muse, mutect2, varscan2
- LEF1 | c.826G>A p.D276N | Missense Mutation (SNP) | VAF 35/142 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as rs1374631633, COSV54471070, COSV99490028; called by muse, mutect2, varscan2
- LRRIQ1 | c.3558-1G>C p.X1186_splice | Splice Site (SNP) | VAF 7/34 reads (21%) | catalogued as COSV67831445; called by muse, mutect2, varscan2
- LTN1 | c.3065A>T p.E1022V | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV63734005; called by muse, mutect2, varscan2
- MAP3K4 | c.3538C>G p.P1180A | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.055); catalogued as COSV62334629; called by muse, mutect2, varscan2
- MPL | c.1348G>C p.E450Q | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.164); catalogued as COSV65246555; called by muse, mutect2, varscan2
- MTMR14 | c.526G>T p.D176Y | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as rs1215572060; called by muse, mutect2, varscan2
- MYH7 | c.4649C>T p.S1550F | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.839); catalogued as rs730880912; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYH9 | c.2334G>C p.K778N | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV53386103; called by muse, varscan2
- MYO18B | c.316G>A p.G106S | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.003); catalogued as rs768030958; called by muse, mutect2, varscan2
- NDST3 | c.466G>C p.E156Q | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.279); catalogued as COSV56615688; called by muse, mutect2, varscan2
- NUMA1 | c.2474C>T p.A825V | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.23); catalogued as rs989808757; called by muse, mutect2, varscan2
- OBSCN | c.15391G>A p.E5131K | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV52783347; called by muse, mutect2, varscan2
- OBSCN | c.21697C>T p.Q7233* | Nonsense Mutation (SNP) | VAF 15/51 reads (29%) | catalogued as rs1188754127; called by muse, mutect2, varscan2
- OR2L3 | c.247G>C p.D83H | Missense Mutation (SNP) | VAF 58/167 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV63455769; called by muse, mutect2, varscan2
- PHAX | c.172C>T p.R58* | Nonsense Mutation (SNP) | VAF 17/49 reads (35%) | catalogued as rs1438066017, COSV52551661; called by muse, mutect2, varscan2
- PLEC | c.6079G>A p.D2027N (on ENST00000322810 / NM_201380.4; = p.D1917N on NM_000445.5) | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.985); catalogued as rs1554696439; called by muse, mutect2
- PTCHD1 | c.2620G>T p.V874L | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.162); catalogued as COSV101037617; called by muse, mutect2
- QTRT2 | c.864C>G p.F288L | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as rs1473492905, COSV55561360, COSV99847050; called by muse, mutect2, varscan2
- RAD21 | c.185G>A p.G62E | Missense Mutation (SNP) | VAF 33/124 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52057760; called by muse, mutect2, varscan2
- RASAL3 | c.656G>A p.R219Q | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as rs367734005; called by muse, mutect2, varscan2
- RASGRP4 | c.1765G>A p.E589K | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99384968; called by muse, mutect2, varscan2
- RASGRP4 | c.1553G>C p.R518T | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.617); catalogued as COSV99384969; called by mutect2, varscan2
- RBM15 | c.97C>T p.Q33* | Nonsense Mutation (SNP) | VAF 12/56 reads (21%) | catalogued as rs1322409510; called by muse, mutect2, varscan2
- RPS25 | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.304); catalogued as COSV57723156; called by muse, mutect2, varscan2
- RYR1 | c.14020C>T p.R4674W | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs779865630; called by muse, mutect2, varscan2
- SCAPER | c.432C>G p.F144L | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100236735; called by muse, mutect2, varscan2
- SEPTIN5 | c.869C>T p.T290M | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV63530516; called by mutect2, varscan2
- SIAH3 | c.629G>A p.R210Q | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs1193045104; called by muse, mutect2, varscan2
- SPDYE3 | c.17C>T p.P6L | Missense Mutation (SNP) | VAF 63/247 reads (26%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.912); catalogued as rs745825464; called by muse, mutect2, varscan2
- STK3 | c.457C>T p.L153F | Missense Mutation (SNP) | VAF 32/51 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV69223063; called by muse, mutect2, varscan2
- TST | c.113C>T p.S38L | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1266419232; called by muse, mutect2, varscan2
- UBR5 | c.572C>T p.S191L | Missense Mutation (SNP) | VAF 27/41 reads (66%) | SIFT deleterious (0); PolyPhen benign (0.122); catalogued as COSV55287446; called by muse, varscan2
- UNC5D | c.764G>T p.W255L | Missense Mutation (SNP) | VAF 23/37 reads (62%) | SIFT deleterious (0); PolyPhen benign (0.246); catalogued as COSV99775711; called by muse, mutect2, varscan2
- USPL1 | c.1153G>A p.E385K | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.103); catalogued as COSV55000319; called by muse, mutect2, varscan2
- WDR70 | c.1750C>G p.L584V | Missense Mutation (SNP) | VAF 75/147 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54284823; called by muse, mutect2, varscan2
- ZNF232 | c.980G>C p.G327A | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs1292671430; called by muse, mutect2, varscan2
- ABCF2 | c.1351G>A p.D451N | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- ACSM4 | c.1298C>T p.S433F | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- ADAMTS20 | c.2092G>A p.D698N | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C1orf116 | c.525G>C p.Q175H | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.826); called by muse, mutect2, varscan2
- CACNA1C | c.3355G>C p.E1119Q | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.751); called by muse, mutect2, varscan2
- CD99L2 | c.367G>A p.D123N | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- CEP57L1 | c.442A>C p.N148H | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- CIR1 | c.925G>A p.E309K | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- CNTNAP3 | c.3043C>G p.Q1015E | Missense Mutation (SNP) | VAF 78/1020 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.186); called by muse, mutect2
- EPC1 | c.1985C>T p.A662V | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- EPHA5 | c.1076C>T p.S359F | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FLNA | c.1174G>C p.E392Q | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- GJB5 | c.549G>C p.K183N | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GLB1 | c.790T>A p.L264M | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GNB1 | c.283C>G p.L95V | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- H2BC8 | c.313G>A p.G105R | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.471); called by muse, mutect2, varscan2
- IFI27L1 | c.299C>T p.S100L | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- LAMA5 | c.7115_7118dup p.L2374Pfs*62 | Frame Shift Ins (INS) | VAF 10/46 reads (22%) | called by mutect2, pindel, varscan2
- MED1 | c.3196C>T p.Q1066* | Nonsense Mutation (SNP) | VAF 13/62 reads (21%) | called by muse, mutect2, varscan2
- MYH10 | c.5098G>A p.E1700K | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.967); called by muse, mutect2
- MYH10 | c.406G>C p.E136Q | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- MYH8 | c.3382G>C p.E1128Q | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- MYLK | c.2477C>T p.A826V | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- NGEF | c.2037G>C p.Q679H | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NGLY1 | c.1586G>C p.R529T | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NUTM2F | c.1346C>T p.S449F | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- PDE1C | c.945G>C p.M315I | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.495); called by muse, mutect2, varscan2
- PLEC | c.7741G>C p.D2581H (on ENST00000322810 / NM_201380.4; = p.D2471H on NM_000445.5) | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- PPM1N | c.1118C>G p.S373* | Nonsense Mutation (SNP) | VAF 10/36 reads (28%) | called by muse, mutect2, varscan2
- PTDSS1 | c.622C>T p.P208S | Missense Mutation (SNP) | VAF 90/218 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- REV3L | c.4859G>C p.S1620T | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.549); called by muse, mutect2
- RNF128 | c.484+1G>A p.X162_splice | Splice Site (SNP) | VAF 16/52 reads (31%) | called by muse, mutect2, varscan2
- RYR2 | c.5015T>A p.V1672E | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SPATA5 | c.400C>G p.L134V | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.6); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SPON1 | c.1990G>A p.E664K | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- STXBP4 | c.1587G>C p.M529I | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TBC1D20 | c.1211G>T p.*404Lext*60 | Nonstop Mutation (SNP) | VAF 20/59 reads (34%) | called by muse, mutect2, varscan2
- TBC1D32 | c.539A>G p.Q180R | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.81); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TG | c.3829C>T p.Q1277* | Nonsense Mutation (SNP) | VAF 10/50 reads (20%) | called by muse, mutect2, varscan2
- TJP1 | c.5002G>C p.E1668Q | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.151); called by muse, mutect2, varscan2
- TNFAIP3 | c.1368del p.P457Lfs*20 | Frame Shift Del (DEL) | VAF 4/18 reads (22%) | called by mutect2, pindel
- TOGARAM2 | c.1643C>T p.S548F | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- TRAPPC8 | c.2671G>C p.E891Q | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.818); called by muse, mutect2, varscan2
- UHMK1 | c.445C>T p.L149F | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ULK4 | c.3505G>C p.D1169H | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- ZNF684 | c.991G>C p.E331Q | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- A4GALT | c.546C>T p.L182= | Silent (SNP) | VAF 14/50 reads (28%) | called by muse, mutect2
- ACTN1 | c.2403C>T p.P801= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as COSV99517780; called by muse, mutect2, varscan2
- ADGRB3 | c.1761G>A p.Q587= | Silent (SNP) | VAF 22/50 reads (44%) | catalogued as rs1241210093, COSV65390717; called by muse, mutect2, varscan2
- APEX2 | c.111C>T p.D37= | Silent (SNP) | VAF 13/55 reads (24%) | catalogued as rs370230204, COSV66624206; called by muse, mutect2, varscan2
- AUTS2 | c.3258G>A p.R1086= | Silent (SNP) | VAF 6/25 reads (24%) | called by muse, mutect2, varscan2
- C1orf210 | c.168C>G p.L56= | Silent (SNP) | VAF 15/37 reads (41%) | catalogued as COSV101382237; called by muse, mutect2, varscan2
- C5AR1 | c.957C>T p.L319= | Silent (SNP) | VAF 13/72 reads (18%) | called by muse, mutect2, varscan2
- CLCA2 | c.1077G>A p.E359= | Silent (SNP) | VAF 13/56 reads (23%) | catalogued as COSV65287532; called by muse, mutect2, varscan2
- COL6A1 | c.441G>A p.L147= | Silent (SNP) | VAF 24/91 reads (26%) | called by muse, mutect2, varscan2
- COX5B | c.81G>C p.A27= | Silent (SNP) | VAF 26/95 reads (27%) | catalogued as COSV51480951, COSV51481078; called by muse, mutect2, varscan2
- DNAAF5 | c.2277G>T p.V759= | Silent (SNP) | VAF 21/79 reads (27%) | catalogued as COSV99859723; called by muse, mutect2, varscan2
- EIF3M | c.270G>A p.L90= | Silent (SNP) | VAF 17/62 reads (27%) | catalogued as rs1339484084; called by muse, mutect2, varscan2
- FAM83A | c.975C>T p.S325= | Silent (SNP) | VAF 3/19 reads (16%) | catalogued as rs1298956026; called by muse, mutect2
- GNB1L | c.960C>A p.L320= | Silent (SNP) | VAF 34/102 reads (33%) | called by muse, mutect2, varscan2
- HCN1 | c.636G>T p.V212= | Silent (SNP) | VAF 44/77 reads (57%) | catalogued as rs752579418, COSV57505838; called by muse, mutect2, varscan2
- JUP | c.1167G>A p.L389= | Silent (SNP) | VAF 14/45 reads (31%) | called by muse, mutect2, varscan2
- JUP | c.537G>C p.L179= | Silent (SNP) | VAF 15/51 reads (29%) | catalogued as COSV60277706; called by muse, mutect2, varscan2
- KANK1 | c.138C>G p.L46= | Silent (SNP) | VAF 14/55 reads (25%) | catalogued as rs1474029263; called by muse, mutect2, varscan2
- MBD6 | c.912G>C p.L304= | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as COSV100851686; called by muse, mutect2, varscan2
- MRPL28 | c.381G>T p.V127= | Silent (SNP) | VAF 19/40 reads (48%) | called by muse, mutect2, varscan2
- MYO5B | c.1284C>G p.L428= | Silent (SNP) | VAF 16/74 reads (22%) | catalogued as COSV53219047; called by muse, mutect2, varscan2
- NDUFA6 | c.249C>G p.V83= | Silent (SNP) | VAF 13/73 reads (18%) | called by muse, mutect2, varscan2
- NFE2L2 | c.1443C>T p.F481= | Silent (SNP) | VAF 10/38 reads (26%) | called by muse, mutect2, varscan2
- PHLDA1 | c.972G>A p.Q324= | Silent (SNP) | VAF 14/44 reads (32%) | called by muse, mutect2, varscan2
- PLEC | c.9804G>A p.L3268= (on ENST00000322810 / NM_201380.4; = p.L3158= on NM_000445.5) | Silent (SNP) | VAF 14/79 reads (18%) | catalogued as rs1554681765, COSV59633104; ClinVar: likely benign; called by muse, mutect2, varscan2
- PLEC | c.7131G>A p.L2377= (on ENST00000322810 / NM_201380.4; = p.L2267= on NM_000445.5) | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as COSV100517104, COSV59632689; called by muse, mutect2, varscan2
- RGS8 | c.393G>A p.T131= (on ENST00000367556 / NM_001369564.2; = p.T149= on NM_033345.3) | Silent (SNP) | VAF 24/77 reads (31%) | catalogued as rs147293552; called by muse, mutect2, varscan2
- RS1 | c.507G>A p.Q169= | Silent (SNP) | VAF 33/117 reads (28%) | called by muse, mutect2, varscan2
- SERBP1 | c.681C>G p.V227= (on ENST00000370995 / NM_001018067.2; = p.V221= on NM_015640.4) | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as COSV63413614; called by muse, mutect2, varscan2
- SGSM2 | c.2760G>A p.K920= (on ENST00000426855 / NM_001098509.2; = p.K965= on NM_014853.3) | Silent (SNP) | VAF 12/49 reads (24%) | catalogued as COSV99280093; called by muse, mutect2, varscan2
- SLC13A1 | c.678C>A p.T226= | Silent (SNP) | VAF 18/69 reads (26%) | called by muse, mutect2, varscan2
- SLC22A7 | c.804T>C p.C268= (on ENST00000372585 / NM_153320.2; = p.C266= on NM_006672.3) | Silent (SNP) | VAF 7/27 reads (26%) | called by muse, mutect2, varscan2
- TGFB1I1 | c.921C>T p.H307= (on ENST00000394863 / NM_001042454.3; = p.H290= on NM_015927.4) | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as COSV62358191; called by muse, mutect2, varscan2
- TRPM5 | c.678C>T p.L226= | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as COSV50157047; called by muse, mutect2
- VAC14 | c.1380G>A p.L460= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as rs373511817; called by muse, mutect2, varscan2
- XRCC6 | c.1146C>T p.F382= | Silent (SNP) | VAF 15/61 reads (25%) | called by muse, mutect2, varscan2
- ZNF768 | c.690G>A p.E230= | Silent (SNP) | VAF 14/32 reads (44%) | called by muse, mutect2, varscan2
- KMT5C | c.570+699C>T | Intron (SNP) | VAF 33/127 reads (26%) | called by muse, mutect2, varscan2
- PEX5L | c.-2G>A | 5'UTR (SNP) | VAF 11/52 reads (21%) | catalogued as COSV99830326; called by muse, mutect2, varscan2
- PKD1L2 | n.4663C>T | RNA (SNP) | VAF 10/37 reads (27%) | catalogued as rs1567623802; called by muse, mutect2, varscan2
- S1PR3 | chr9:88991214 G>A | 5'Flank (SNP) | VAF 4/16 reads (25%) | catalogued as rs542361091, COSV100560960; called by muse, varscan2
